Somatic mutation profile of tumor specimen TCGA-M7-A721-01A (aliquot TCGA-M7-A721-01A-12D-A32B-08) from TCGA case TCGA-M7-A721, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.0 years (25,585 days).
Specimen TCGA-M7-A721-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 540f9c5b-1aee-4fc3-b733-419b24b599a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-M7-A721-10A (Blood Derived Normal), aliquot TCGA-M7-A721-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d9a37e6-6473-4423-9731-24251ad4d9d0

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, Nonsense Mutation 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP5 | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100565330; called by muse, mutect2, varscan2
- ASTN2 | c.3727C>A p.H1243N (on ENST00000313400 / NM_001365069.1; = p.H1192N on NM_014010.5) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.355); catalogued as COSV99940743; called by muse, mutect2, varscan2
- DDX53 | c.117G>T p.Q39H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.264); catalogued as COSV60069651; called by muse, mutect2, varscan2
- DDX6 | c.506T>G p.V169G | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99870296; called by muse, mutect2, varscan2
- ERCC6L | c.3242G>C p.S1081T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV100559092; called by muse, mutect2, varscan2
- FBXW11 | c.1277G>T p.R426M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99440388; called by muse, mutect2, varscan2
- FREM2 | c.3619G>C p.V1207L | Missense Mutation (SNP) | VAF 50/384 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99748551; called by muse, mutect2, varscan2
- HEMK1 | c.635T>G p.I212S | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99231692; called by muse, mutect2
- HEXB | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99714288; called by muse, mutect2
- ITGAV | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99654826; called by muse, mutect2
- KIAA2026 | c.6005C>G p.S2002* | Nonsense Mutation (SNP) | VAF 8/122 reads (7%) | catalogued as COSV101199013; called by muse, mutect2
- LCE2D | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV64228990; called by muse, mutect2
- LRRK1 | c.5620G>A p.D1874N | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs565686156, COSV99439577; called by muse, mutect2
- MYH6 | c.3913C>T p.R1305W | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763328656, COSV62450708; called by muse, mutect2, varscan2
- MYH9 | c.1643A>T p.Q548L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as COSV99338690; called by muse, mutect2, varscan2
- PPARGC1A | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs762406141, COSV99337842; called by muse, mutect2, varscan2
- RGS6 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100666113; called by muse, mutect2, varscan2
- SPTB | c.397A>T p.M133L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.208); catalogued as COSV101072106; called by muse, mutect2
- TMEM132E | c.2327C>A p.P776H (on ENST00000321639; = p.P866H on NM_001304438.2) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV100396226; called by muse, mutect2
- ZNF112 | c.1897G>C p.G633R (on ENST00000337401 / NM_001083335.2; = p.G627R on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/263 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100495723; called by muse, mutect2
- ZNF417 | c.1117G>T p.V373F | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV100364216; called by muse, mutect2
- ASPA | c.526+1del | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | called by mutect2, pindel
- TRBV29-1 | c.62A>C p.Q21P | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AQR | c.1365G>A p.L455= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV99333870; called by muse, mutect2
- BNC2 | c.2952C>T p.S984= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs368842595; called by muse, mutect2, varscan2
- FBN3 | c.8310T>G p.P2770= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV99495150; called by muse, mutect2, varscan2
- NFASC | c.3714T>C p.S1238= (on ENST00000339876 / NM_001378329.1; = p.S1167= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100363749; called by muse, mutect2
- TLR8 | c.1086C>T p.N362= (on ENST00000218032 / NM_138636.5; = p.N380= on NM_016610.4) | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as COSV99486977; called by muse, mutect2
- USP49 | c.753C>T p.G251= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs765120920, COSV99790204; called by muse, mutect2, varscan2
- SNORD116-11 | n.2G>C | RNA (SNP) | VAF 6/63 reads (10%) | catalogued as rs540876214; called by muse, mutect2, varscan2
